Surgical pathology report (de-identified scan), TCGA case TCGA-HQ-A5ND, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HQ-A5ND-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	Transitional cell carcinoma
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	Resection - radical cystoprostatectomy
Site of Tissue/Primary (Histology)	Bladder
Tumour Size (cm)	8
Histology	Transitional cell carcinoma
Grade/Differentiation	III
Pathological T	T4
Pathological N	N1
Clinical M	M0
Histology Comments	bladder - tumour - 90% tumour - no necrosis

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

ICD-O-3
path Carcinoma, transitional cell NOS
8126/3
OSCE Carcinoma, urothelial NOS
8126/3
Site: Bladder NOS C67.9
7/21/13

Source: NCI Genomic Data Commons file 69a10c2c-e7f2-4eb7-8a5c-f5f175a152c0 (TCGA-HQ-A5ND.90EBB6AD-C8DC-44FE-AE88-674F15041327.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).